FM case AD176 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/463e6b1e-16a7-44c7-84da-d09c71a6105d

Male, 61.5 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the colon. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Tumor.
